Somatic mutation profile of tumor specimen ALCH-B408-TTP1-A (aliquot ALCH-B408-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B408, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 76.7 years (28,018 days).
Specimen ALCH-B408-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbafcd4b-af6c-413f-ab46-ed67a1ac4079.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B408-NB1-A (Blood Derived Normal), aliquot ALCH-B408-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f018c24-5adc-4cd3-b7e1-0c9b1475c73f

The open-access MAF lists 69 somatic variants for this specimen: 49 protein-altering or splice-affecting, 12 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 12, RNA 4, Splice Site 2, In Frame Del 1, Frame Shift Del 1, 3'UTR 1, 5'Flank 1, Nonsense Mutation 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 67/389 reads (17%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- BAZ1A | c.3464G>A p.R1155Q | Missense Mutation (SNP) | VAF 28/498 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775527075; called by muse, mutect2
- CDH8 | c.1774T>A p.L592M | Missense Mutation (SNP) | VAF 131/782 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54851192; called by muse, mutect2, varscan2
- CFP | c.521G>T p.C174F | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1359369286; called by muse, mutect2
- DTX4 | c.1618G>C p.G540R | Missense Mutation (SNP) | VAF 44/238 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286999974; called by muse, varscan2
- DUOXA1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1177057953, COSV50993097; called by muse, mutect2
- ELMOD3 | c.932T>C p.F311S | Missense Mutation (SNP) | VAF 61/365 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs1018113481; called by muse, mutect2, varscan2
- FBXO33 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 32/216 reads (15%) | catalogued as COSV53233777; called by muse, mutect2, varscan2
- LMTK2 | c.3752C>T p.S1251F | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV52003719; called by muse, mutect2, varscan2
- MCM7 | c.1825A>G p.I609V | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.058); catalogued as rs1270400912, COSV57997474; called by muse, mutect2, varscan2
- MKKS | c.421C>A p.P141T | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV100726333, COSV61399379; called by muse, mutect2, varscan2
- NES | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV100957917; called by muse, mutect2
- PPP1R13B | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746912422; called by muse, mutect2, varscan2
- PRKN | c.7+2T>C p.X3_splice | Splice Site (SNP) | VAF 57/318 reads (18%) | catalogued as rs950518517; called by muse, mutect2, varscan2
- SLC26A2 | c.1360C>G p.Q454E | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1453093292; called by muse, mutect2, varscan2
- TNS1 | c.4204C>T p.P1402S | Missense Mutation (SNP) | VAF 21/285 reads (7%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.943); catalogued as rs765374803; called by muse, mutect2
- TRMT2B | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 65/319 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100105754; called by muse, mutect2, varscan2
- TRMT2B | c.526G>C p.G176R | Missense Mutation (SNP) | VAF 68/324 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.57); catalogued as COSV100105110; called by muse, mutect2, varscan2
- USH2A | c.14516C>T p.T4839M | Missense Mutation (SNP) | VAF 47/291 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as rs139065588, COSV56360228, COSV56383574; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ANTXRL | c.742T>A p.S248T | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- C6orf132 | c.2393G>A p.G798E | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDK16 | c.1484A>G p.E495G | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CMYA5 | c.6360G>T p.K2120N | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CP | c.1858A>T p.M620L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- CP | c.1856A>G p.K619R | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.793); called by muse, mutect2
- CYP2W1 | c.1102A>G p.T368A | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- DACH1 | c.1911A>T p.R637S (on ENST00000619232 / NM_001366712.1; = p.R383S on NM_004392.6) | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DLD | c.920A>G p.D307G | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DOP1A | c.6474C>G p.S2158R | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- DPH5 | c.540G>C p.K180N | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.188); called by muse, mutect2
- DUOXA1 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ERAL1 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 23/517 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- EXOC1 | c.1543T>G p.F515V | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.224); called by muse, varscan2
- FBXL13 | c.1323C>A p.D441E | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- FREM2 | c.4237T>C p.S1413P | Missense Mutation (SNP) | VAF 115/285 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- GABRR1 | c.1340G>A p.S447N | Missense Mutation (SNP) | VAF 17/402 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.02); called by muse, mutect2
- HOXA1 | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 36/313 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- JAKMIP1 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 44/429 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- MTRR | c.935C>A p.T312N (on ENST00000264668; = p.T285N on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/524 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NFX1 | c.1855G>A p.V619M | Missense Mutation (SNP) | VAF 98/498 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- NKRF | c.1598G>A p.R533K | Missense Mutation (SNP) | VAF 13/318 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.132); called by muse, mutect2
- NUMA1 | c.3836del p.N1279Tfs*37 | Frame Shift Del (DEL) | VAF 91/294 reads (31%) | called by mutect2, pindel, varscan2
- OTOGL | c.3460A>T p.T1154S (on ENST00000547103; = p.T1145S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- PLEKHG3 | c.1137T>G p.D379E (on ENST00000394691; = p.D435E on NM_001308147.2) | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.113); called by muse, mutect2
- RSF1 | c.3305_3341+5del p.X1102_splice | Splice Site (DEL) | VAF 14/88 reads (16%) | called by mutect2, pindel
- SMYD4 | c.998C>A p.T333K | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- THOC2 | c.2755A>T p.M919L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.01); called by muse, mutect2
- TUBGCP6 | c.95G>C p.R32T | Missense Mutation (SNP) | VAF 16/493 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.15); called by muse, mutect2
- ZIK1 | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ADAMTS10 | c.1407G>A p.P469= | Silent (SNP) | VAF 180/413 reads (44%) | catalogued as rs149014496; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1I | c.5202C>T p.D1734= | Silent (SNP) | VAF 115/384 reads (30%) | catalogued as rs780538955, COSV100361272; called by muse, mutect2, varscan2
- EME1 | c.756C>A p.I252= | Silent (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- GFM2 | c.939T>C p.T313= | Silent (SNP) | VAF 18/78 reads (23%) | called by muse, mutect2, varscan2
- IGHD | c.700C>T p.L234= | Silent (SNP) | VAF 69/562 reads (12%) | catalogued as rs1292028551; called by muse, varscan2
- MSLNL | c.555C>T p.D185= | Silent (SNP) | VAF 26/183 reads (14%) | catalogued as rs747952634; called by muse, mutect2, varscan2
- RYR1 | c.4761C>T p.A1587= | Silent (SNP) | VAF 19/519 reads (4%) | catalogued as rs1387909457; called by muse, mutect2
- RYR3 | c.1755C>T p.I585= | Silent (SNP) | VAF 35/217 reads (16%) | called by muse, mutect2, varscan2
- SIGLEC9 | c.312G>C p.L104= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV51583762; called by muse, mutect2
- TSC22D3 | c.312G>A p.E104= | Silent (SNP) | VAF 64/337 reads (19%) | catalogued as COSV59778631; called by muse, mutect2, varscan2
- ZNF600 | c.1065G>A p.E355= | Silent (SNP) | VAF 26/179 reads (15%) | catalogued as rs1468657500; called by muse, mutect2, varscan2
- ZNF764 | c.237G>A p.E79= | Silent (SNP) | VAF 14/363 reads (4%) | called by muse, mutect2
- CYYR1 | c.-164C>T | 5'UTR (SNP) | VAF 23/136 reads (17%) | catalogued as rs1162872825; called by muse, mutect2, varscan2
- DDX17 | c.1448-88C>T | Intron (SNP) | VAF 5/26 reads (19%) | catalogued as rs768739852, COSV99318267; called by muse, mutect2
- FER1L4 | n.3061G>C | RNA (SNP) | VAF 22/213 reads (10%) | catalogued as rs1490061676; called by muse, mutect2, varscan2
- FER1L4 | n.2833G>A | RNA (SNP) | VAF 19/199 reads (10%) | called by muse, mutect2, varscan2
- FER1L4 | n.2608G>A | RNA (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- FEZ1 | chr11:125496792 C>T | 5'Flank (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- GUCY1B2 | n.887G>A | RNA (SNP) | VAF 27/164 reads (16%) | catalogued as rs1189310823; called by muse, mutect2, varscan2
- SCN4B | c.*2328A>T | 3'UTR (SNP) | VAF 36/244 reads (15%) | catalogued as rs1182077088; called by muse, mutect2, varscan2
